CCDI case PBCIKU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/47bc5e45-b433-4b53-a012-534dd951b2e6

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 6.3 years (2,299 days).

Biospecimens (3 samples)
- Samples 0DSS56, 0DSS5R (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSS6B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
